Surgical pathology report (de-identified scan), TCGA case TCGA-MV-A51V, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Minnesota, specimen TCGA-MV-A51V-01A (Primary Tumor).

[page 1 of 7]
SPECIMEN(S):

- A: Left pelvic lymph nodes
- B: Right pelvic lymph nodes
- C: Bladder, prostate, seminal vesicles
- D: Left common iliac lymph nodes
- E: Right common iliac lymph nodes
- F: Hernia sac

ICD-0-3

carcinoma, papillary urothelial 8130/7
CQCF Site: bladder, anterior wall C67.3
Path: bladder, NOS C67.9

hw
10/4/12

FINAL DIAGNOSIS:

A. Left pelvic lymph nodes:

- Ten benign lymph nodes with no evidence of malignancy (0/10 lymph nodes).

B. Right pelvic lymph nodes:

- Ten benign lymph nodes with no evidence of malignancy (0/10 lymph nodes).

C. Bladder, prostate, seminal vesicles:

- Histologic type: Papillary urothelial (transitional cell) carcinoma
- Histologic grade: High-grade
- Tumor size: 5.6 x 2.1 cm; Pattern of growth: Papillary. Focal, with

Prior Malignancy History (bladder)	☒	

hw
10/4/12

[page 2 of 7]
extensive carcinoma in-situ

- Location: Left and right, anterior wall.
- Extent of invasion:
- Angiolymphatic invasion: Absent.
- Involvement of prostate: Absent.
- Surgical margins:
- Soft tissue: Negative.
- Urethra: Negative.
- Ureters: Carcinoma in-situ present at left ureter margin.
- Paravesical: Negative.
- Lymph nodes: All negative (Specimens A, B, D, positive/total: 0/23)
- Additional pathologic findings:
- Dysplasia and carcinoma in-situ: Present, multifocal.
- Inflammation: Focal chronic inflammation and previous biopsy site changes.
- Ulceration: Absent.

D. Left common iliac lymph nodes:

- Three benign lymph nodes with no evidence of malignancy (0/3 lymph nodes).

E. Right common iliac lymph nodes:

- Benign fibroadipose tissue with no evidence of malignancy.
(No lymph node tissue present).

[page 3 of 7]
F. Hernia sac:

- Benign hernia sac.

AJCC Staging:

pT3a, pN0, pM0.

G3.

COMMENT:

The tumor represents a high-grade urothelial carcinoma. Sections of the left side of the tumor show microscopic infiltration through the detrusor muscle into perivesical soft tissues for a distance of 0.1 cm.

The tumor does not extend to the radial soft tissue margin.

Carcinoma in-situ is present in every section of the bladder and is present at left ureteral margin. Previous biopsy situ changes are observed in sections of the trigone. Sections of the prostate show benign prostatic tissue with no tumor extension.

I have personally reviewed all specimens and or slides, including the listed special stains, and used them with my medical judgement to determine the final diagnosis.

CLINICAL HISTORY:

[page 4 of 7]
This is a ear-old male with a history of bladder cancer, undergoes radical cystectomy with attached prostate and lymph node dissection.

GROSS:

Six specimens are received, each labeled with the patient's name and hospital identification number.

A. Specimen A is designated "left pelvic lymph nodes." The specimen consists of a 6.5 x 5.2 x 3.2 cm aggregate of yellow lobulated adipose tissue containing multiple potential lymph nodes ranging in size from 2.0 to 0.4 cm in greatest dimension. All lymph nodes are removed and submitted in six cassettes.

B. Specimen B is designated "right pelvic lymph nodes." The specimen consists of a 6.3 x 5.5 x 2.2 cm aggregate of yellow lobulated adipose tissue containing multiple potential lymph nodes ranging in size from 2.5 to 0.5 cm in greatest diameter. All lymph nodes are submitted in six cassettes.

C. Specimen C is designated "bladder, prostate, seminal vesicles." The specimen consists of a 19.2 x 13.1 x 4.5 cm bladder with associated adipose tissue. The prostate measures 4.0 x 2.9 x 2.8 cm. The specimen is inked as follows: right hemisphere - blue, left hemisphere - black. The apical margin is removed and submitted for

[page 5 of 7]
frozen section diagnosis as CFS1. The remainder of the specimen is open along the anterior midline revealing a papillary, exophytic appearing lesion tethered to the anterior aspect of the mucosal surface measuring 5.6 x 2.1 cm, extending 0.5 cm into the lumen. This area is located approximately 0.2 cm to the right ureteral orifice, 1.2 cm to the left ureteral orifice, 4.0 cm to the apical margin, and 1.5 cm to the trigone. Sectioning of the lesion reveals that it infiltrates into the wall. Grossly the lesion is completely excised. The surrounding mucosal surface has a tan-red appearance. No additional lesions are present. The prostate is sectioned revealing a fibrotic tan-gray cut surface. Grossly no lesions are identified within the prostate. The specimen is extensively sampled in 21 cassettes. No lymph nodes are identified within the associated adipose tissue. Representative tissue was procured for potential future studies from specimen C.

D. Specimen D is designated "left common iliac lymph nodes."

The specimen consists of a 2.6 x 2.6 x 1.5 cm aggregate of yellow lobulated adipose tissue containing an unremarkable yellow lobulated cut surface. No lymph nodes are grossly identified. The specimen is entirely submitted in two cassettes.

E. Specimen E is designated "right common iliac." The specimen consists of a 2.0 cm aggregate of yellow lobulated adipose tissue. Grossly the specimen is unremarkable. No lymph nodes are grossly identified. The specimen is entirely submitted in two cassettes.

[page 6 of 7]
F. Specimen F is designated "hernia sac." The specimen consists of a tan-red portion of fibromembranous soft tissue measuring 1.0 x 0.8 x 0.3 cm. One surface has a smooth and intact appearance, the opposite is roughened. No evidence of thickening or complexity is identified. The specimen is sectioned and submitted in cassette F.

Summary of Sections:

A1-A4 - lymph nodes.

A5 - single lymph node.

A6 - single lymph node.

B1-B3 - lymph nodes.

B4 - single lymph node.

B5-B6 - single lymph node (same node).

C1 - portion for frozen section.

C2 - right ureter margin.

C3 - left ureter margin.

C4 -C5 - lesion, right bladder.

C6 - lesion, right ureteral orifice.

C7 - lesion, left ureteral orifice.

C8-C9 - additional lesion, left hemisphere.

C10 - uninvolved right bladder.

C11 - uninvolved bladder dome.

C12 - uninvolved bladder, left.

C13 - trigone.

[page 7 of 7]
C14-C17 - prostate, right hemisphere.

C18-C21 - prostate, left hemisphere.

D1-D2 - left common iliac lymph node, entirely submitted.

E1-E2 - right common iliac, entirely submitted.

F - hernia sac.

INTRAOPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS:

CFS1: Bladder, prostate, seminal vesicles - "Urinary bladder, distal margin at apex of bladder: Negative for urothelial cancer on section sampled."

MICROSCOPIC:

Microscopic examination is performed.

Source: NCI Genomic Data Commons file ef13c837-fd7a-4aad-9026-d99ee03b5e18 (TCGA-MV-A51V.E6737FA1-2DEE-4CF3-AE45-6866FF1F7FF4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).